HCMI case HCM-BROD-0923-C64 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba085153-6dbd-4134-a78d-1be7579f8369

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2009; Vital status: Alive.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 9.9 years (3,604 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; COG renal stage: Stage III; Sites of involvement: Lymph Node, Regional; Wilms tumor histologic subtype: Favorable.
   Pathology details: Anaplasia present: No; Gross tumor weight: 473 g.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 0 days; Days to treatment end: 183 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 30 days; Days to treatment end: 153 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 30 days; Days to treatment end: 61 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 669 days (1.8 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 580.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0923-C64-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0923-C64-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
